Somatic mutation profile of tumor specimen MP2PRT-PARWCC-TMP1-A (aliquot MP2PRT-PARWCC-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARWCC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,685 days).
Specimen MP2PRT-PARWCC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2c8a49e-d44f-4231-9f2c-389e675d4f1f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARWCC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARWCC-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/97bcd41b-37b3-4f6e-b6cc-829627c13146

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIG1 | c.244C>T p.L82F | Missense Mutation (SNP) | VAF 74/555 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs780227222; called by muse, mutect2, varscan2
- CASKIN2 | c.3055G>A p.A1019T | Missense Mutation (SNP) | VAF 226/1126 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs746688141; called by muse, mutect2, varscan2
- CREBBP | c.1318C>T p.R440* | Nonsense Mutation (SNP) | VAF 92/511 reads (18%) | catalogued as COSV52118985; called by muse, mutect2, varscan2
- H1-2 | c.328A>T p.K110* | Nonsense Mutation (SNP) | VAF 134/652 reads (21%) | catalogued as COSV59193472; called by muse, mutect2, varscan2
- NCEH1 | c.415C>T p.R139C (on ENST00000538775; = p.R107C on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/558 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs577740696, COSV99859809; called by muse, mutect2, varscan2
- PCDHA13 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 88/611 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs782704587, COSV56482908; called by muse, mutect2, varscan2
- SCN7A | c.2988C>A p.F996L | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV69274448, COSV69274821; called by muse, mutect2, varscan2
- TYW1 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 111/521 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148741933; called by muse, mutect2, varscan2
- ACSS3 | c.633T>G p.I211M | Missense Mutation (SNP) | VAF 68/283 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FLRT2 | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 125/619 reads (20%) | called by muse, mutect2, varscan2
- AJAP1 | c.405G>A p.S135= | Silent (SNP) | VAF 256/1030 reads (25%) | catalogued as rs1230640332, COSV65448938; called by muse, mutect2, varscan2
- CCAR2 | c.1674G>A p.K558= | Silent (SNP) | VAF 99/515 reads (19%) | called by muse, mutect2, varscan2
- MECR | c.591G>T p.G197= | Silent (SNP) | VAF 99/427 reads (23%) | called by muse, mutect2, varscan2
